Somatic mutation profile of tumor specimen HCM-CSHL-0081-C25-01A (aliquot HCM-CSHL-0081-C25-01A-11D-A78M-36) from HCMI case HCM-CSHL-0081-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 57.9 years (21,139 days).
Specimen HCM-CSHL-0081-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c35adb9-a47e-4fb1-82f6-0998b54bbc00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0081-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0081-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22e9b593-8827-434c-b488-28d4620f6407

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Intron 4, 3'Flank 2, Splice Region 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/346 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 42/318 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKFN1 | c.3799C>T p.R1267C (on ENST00000653862; = p.R1120C on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs764552239, COSV73720123; called by muse, mutect2, varscan2
- ANKRD44 | c.1650+8G>T | Splice Region (SNP) | VAF 36/318 reads (11%) | catalogued as rs1559044801; called by muse, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2
- FKBP9 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.381); catalogued as rs375139220; called by muse, mutect2
- GLT6D1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183429273; called by muse, mutect2, varscan2
- IKBKB | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100645818; called by muse, mutect2, varscan2
- NFASC | c.1076G>A p.R359Q (on ENST00000339876 / NM_001378329.1; = p.R370Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs767453033, COSV58366173; called by muse, mutect2, varscan2
- OR9I1 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100110371; called by muse, mutect2, varscan2
- TECTA | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as rs918069755; called by muse, mutect2, varscan2
- TEX13A | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1412367990, COSV100782132, COSV61161595; called by muse, mutect2, varscan2
- CCDC18 | c.2200A>T p.I734F (on ENST00000343253 / NM_001306076.1; = p.I735F on NM_206886.4) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CFAP65 | c.4157T>G p.V1386G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CR1 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPYS | c.456T>A p.D152E | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LPIN1 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- MYH11 | c.4366T>G p.L1456V | Missense Mutation (SNP) | VAF 63/479 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MYH9 | c.4156G>A p.V1386M | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PANK4 | c.2227C>A p.L743I | Missense Mutation (SNP) | VAF 61/497 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- POLE | c.670T>G p.Y224D | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RABGEF1 | c.122A>G p.N41S (on ENST00000439720 / NM_001287061.2; = p.N28S on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF150 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ROS1 | c.6088G>T p.E2030* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3662-1G>T p.X1221_splice | Splice Site (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2, varscan2
- STK11 | c.433del p.E145Rfs*16 | Frame Shift Del (DEL) | VAF 41/322 reads (13%) | called by mutect2, pindel, varscan2
- UBASH3B | c.755_757del p.R252_F253delinsL | In Frame Del (DEL) | VAF 18/181 reads (10%) | called by mutect2, pindel
- CHTF18 | c.99G>A p.S33= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1043211685; called by muse, mutect2, varscan2
- DDX27 | c.102G>A p.A34= | Silent (SNP) | VAF 38/377 reads (10%) | catalogued as rs112518064, COSV65629814; called by muse, mutect2
- DNAH3 | c.3450C>T p.N1150= | Silent (SNP) | VAF 34/328 reads (10%) | catalogued as rs1251598012; called by muse, mutect2
- FBXW5 | c.54C>T p.F18= | Silent (SNP) | VAF 101/409 reads (25%) | catalogued as rs775259992; called by muse, mutect2, varscan2
- GRK7 | c.33C>T p.I11= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs868864461; called by muse, mutect2, varscan2
- IGHG2 | c.471C>T p.Y157= | Silent (SNP) | VAF 79/579 reads (14%) | catalogued as rs374420820; called by muse, mutect2, varscan2
- MYPN | c.2691A>G p.R897= | Silent (SNP) | VAF 42/331 reads (13%) | called by muse, mutect2, varscan2
- PTX4 | c.1149G>A p.V383= (on ENST00000447419 / NM_001328608.2; = p.V378= on NM_001013658.1) | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs1379329224; called by muse, mutect2, varscan2
- RP1 | c.868T>C p.L290= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV55115442; called by muse, mutect2, varscan2
- TLR6 | c.1674T>A p.S558= | Silent (SNP) | VAF 35/254 reads (14%) | called by muse, mutect2, varscan2
- AC012464.1 | chr12:93894072 del G | 3'Flank (DEL) | VAF 35/265 reads (13%) | called by mutect2, pindel, varscan2
- AMACR | c.739+1138_739+1139insA | Intron (INS) | VAF 22/161 reads (14%) | called by mutect2, pindel
- DCDC1 | c.2715+8769A>C | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- MDM2 | c.175-1135_175-1128del | Intron (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel, varscan2
- TANGO2 | c.380+161G>T | Intron (SNP) | VAF 34/268 reads (13%) | catalogued as rs781272776; called by muse, mutect2, varscan2
- USP15 | chr12:62417182 del G | 3'Flank (DEL) | VAF 7/62 reads (11%) | catalogued as rs766005728; called by pindel, varscan2
- USP27X | chrX:49878441 G>C | 5'Flank (SNP) | VAF 89/319 reads (28%) | called by muse, mutect2, varscan2
